Somatic mutation profile of tumor specimen MP2PRT-PASNRU-TMP1-A (aliquot MP2PRT-PASNRU-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNRU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,711 days).
Specimen MP2PRT-PASNRU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74b39f68-4b6e-4c0b-be9e-55c0f0411599.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNRU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNRU-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c9483d0-cd34-4114-ba6b-57cc8b529eb8

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1158482557, COSV56413602; called by muse, mutect2
- ASTL | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 41/480 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs774657969, COSV60904191; called by muse, mutect2
- PPP1R3C | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs369171784; called by muse, mutect2
- CHD4 | c.3719C>T p.A1240V (on ENST00000357008 / NM_001363606.2; = p.A1253V on NM_001273.5) | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KNDC1 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 30/525 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PRDM9 | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- SLC22A7 | c.477T>A p.A159= (on ENST00000372585 / NM_153320.2; = p.A157= on NM_006672.3) | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
